Surgical pathology report (de-identified scan), TCGA case TCGA-55-6982, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6982-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology

Histopathological Examination

Path#:

Collected:

Received:

Complete:

Pre-Op Diagnosis : Lung Cancer

Order Physician :

Specimens :

Lymph Node, St 4, Lower Paratracheal
Lymph Node, St 4, Lower Paratracheal
Lung Biopsy, right lower lobe nodule
Lymph Node, St 9, Pulmonary Ligament
Lung, Right Lower Lobe
Lymph Node, Right Hilar
Lymph Node, St 4, Lower Paratracheal
Lymph Node, St 8, Paraesophageal
Lymph Node, St 4, Lower Paratracheal
Lymph Node, St 9, Pulmonary Ligament
Lung Biopsy, right lower lobe nodule
Lymph Node, Right Hilar
Lymph Node, St 4, Lower Paratracheal
Lung, Right Lower Lobe
Lymph Node, St 8, Paraesophageal

Frozen Diagnosis : Block# : A-1
Re-Ex? : no
FS-Diag : Benign lymph node
Comment : none
Consult by: none
Block# : B-1
Re-Ex? : no
FS-Diag : Benign lymph node
Comment : none
Consult by: none
Block# : E-1
Re-Ex? : no
FS-Diag : Bronchial margin free of tumor
Comment : none
Consult by: none
Block# : E-2
Re-Ex? : yes
FS-Diag : Bronchial margin free of tumor
Comment : none
Consult by: none
Block# : E-3
Re-Ex? : yes

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#

Path #:

Visit #:

Page 1 of 4

[page 2 of 4]
FS-Diag : Non-small cell carcinoma.
Comment : none
Consult by: none

Report

: GROSS EXAMINATION.

A. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station four, lower paratracheal. The specimen consists of an oval pink tan fragment of lymphoid tissue. The specimen measures 1.0 x 1.0 x 0.4 cm. The specimen is totally submitted for frozen section.

FROZEN SECTION DIAGNOSIS: Benign lymph node.

B. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station four, lower paratracheal. The specimen consists of an ovoid pink tan fragment of lymphoid tissue which measures 1.0 x 0.8 x 0.4 cm. The specimen is totally submitted for frozen section.

FROZEN SECTION DIAGNOSIS: Benign lymph node.

C. The specimen is received in a container labeled with the name of the patient and labeled as lung biopsy, right lower lobe nodule. The specimen consists of a gray pink wedge biopsy of lung tissue which measures and 6.5 x 3.0 x 1.5 cm. The specimen has a palpable 0.8 cm calcified nodule. The serosal surface exhibits anthracotic stippling. The surgical margins are closed with rows of silver colored metal staples. The staple margin is removed and the margin is marked with ink. The specimen is serially sectioned and the calcified nodule is submitted in block one for routine processing following rapid decalcification. The remaining specimen except for the stapled margin is submitted in blocks two through four.

D. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station nine, pulmonary ligament. The specimen consists of an ovoid piece of gray tan rubbery tissue which measures 1.2 x 0.7 x 0.3 cm. The specimen is bisected revealing an anthracotic lymph node. The specimen is totally submitted.

E. The specimen is received in a container labeled with the name of the patient and labeled as lung, right lower lobe. The specimen consists of a gray pink piece of lung tissue which measures 18 x 8 x 4.5 cm. The serosal surface exhibits anthracotic stippling. The surgical margin is closed with rows of silver colored metal staples. The serosal surface is puckered and umbilicated. This area is marked with ink. Under this area is a gray tan indurated nodule which measures 3.5 cm in greatest dimension. This nodule is located 1.2 cm from the nearest stapled margin. A frozen section is performed on the bronchial margins in two blocks with a frozen section on the tumor nodule on frozen section block three.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#:

Path #:
Visit #:

Page 2 of 4

[page 3 of 4]
FROZEN SECTION DIAGNOSIS: E-1, UL bronchus-bronchial margin free of tumor, E-2, lower bronchus- bronchial margin free of tumor. E-3, tumor nodule- non-small cell carcinoma.

The stapled surgical margin is removed and the margin is marked with ink. Additional sections of bronchial margins are submitted in block four, anthracotic lymph nodes are sampled in block five, tumor nodule and inked margin are sampled in block six. The umbilicated area is sampled in block seven. The area of tumor appears to be within 0.5 cm of the closest bronchial margin and is sampled in block eight. The remainder of the specimen is serially sectioned. Sectioning reveals a 0.3 cm nodule distant of the primary nodule. This nodule is submitted in block nine. A representative section of normal appearing lung tissue is submitted in block 10.

F. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, right hilar. The specimen consists of an ovoid piece of blue gray rubbery tissue which measures 2.0 x 0.6 x 0.5 cm. The specimen is sectioned revealing an anthracotic lymph node. The specimen is totally submitted.

G. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station four, lower paratracheal. The specimen consists of two shaggy fragments of gray tan soft tissue measuring in aggregate 1.5 x 0.8 x 0.3 cm. The specimen is totally submitted.

H. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station eight, paraesophageal. The specimen consists of a gray tan anthracotic lymph node measuring 0.5 x 0.5 x 0.3 cm. The specimen is totally submitted.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. Lymph node, station 4, lower paratracheal biopsy:
Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

B. Lymph node, station 4, lower paratracheal biopsy:
Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

C. Lung, right lower lobe, wedge biopsy: Calcified granuloma.
[T-28000 M-09470 V71.7 P3-44070]

D. Lymph node, station 9 biopsy: Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

E. SPECIMEN TYPE: Lobectomy.
LATERALITY: Right lower.
TUMOR SITE: Lower lobe.
TUMOR SIZE: 3.5 cm.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 4 of 4]
[REDACTED]

HISTOLOGIC TYPE: Adenocarcinoma, not otherwise specified.
HISTOLOGIC GRADE: Grade III, poorly differentiated.
PRIMARY TUMOR (PT): T2: Tumor greater than 3 cm in greatest dimension.
REGIONAL LYMPH NODES (PN): N1: Metastases in ipsilateral peribronchial and ipsilateral hilar lymph nodes.
NUMBER EXAMINED: Two.
NUMBER INVOLVED: One.
DISTANT METASTASIS: MX.
MARGINS: Margins uninvolved by invasive carcinoma.
DISTANCE OF INVASIVE FROM CLOSEST MARGIN: 5 mm.
SPECIFY MARGIN: Lower lobe bronchus.
DIRECT EXTENSION OF TUMOR: Visceral pleura.
VENOUS (LARGE VESSEL) INVASION (V): Present.
ARTERIAL (LARGE VESSEL) INVASION: Present.
LYMPHATIC (SMALL VESSEL) INVASION (L): Present.
ADDITIONAL PATHOLOGIC FINDINGS: Calcified granuloma peribronchial lymph node.
[T-28000 M-81403 162.9 P3-44090]

Intradepartmental consultation was obtained.

F. Lymph node, right hilar biopsy: Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

G. Lymph node, station 4, lower paratracheal biopsy: Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

H. Lymph node, station 8, periesophageal biopsy: Negative for malignancy.
[T-C4000 M-09470 V71.1 P3-44050]

[REDACTED]

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#:

Path #:
Visit #:

Page 4 of 4

Source: NCI Genomic Data Commons file 89f014c8-4833-4178-9f69-38ae299a7711 (TCGA-55-6982.54E65072-9BEA-41D0-B976-5F5723379C51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).